Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TY, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TY-01A (Primary Tumor).

1CD-0-3

carcinoma, infiltrating ductal, NOS 8500/3

Site: breast, NOS C50.9

Breast, right, simple mastectomy: Infiltrating ductal carcinoma, Nottingham grade III (of III) is identified forming a 2.4 x 2.2 x 1.8 cm mass (AJCC pT2) in the right upper outer quadrant of the breast. A significant component of in situ carcinoma is not identified. A benign fibroadenoma (0.6 x 0.4 x 0.4 cm) is identified in the upper inner quadrant. Skin, nipple, and resection margins are free of tumor (closest is anterior/superior, free by 3.8 cm). Multiple (8) right axillary lymph nodes are negative for tumor.

Lymph nodes, right axillary sentinel, excision: Multiple (7) right axillary sentinel lymph nodes are negative for tumor [AJCC pNo(sn-)]. Blue dye is identified in right axillary sentinel lymph nodes No.1A and No.1B. Blue dye is not identified in right axillary sentinel lymph nodes No.1C, No.1D, No.1E, No.2, and No.3. Immunohistochemical cyokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Breast, left, simple mastectomy: Benign breast tissue with non-proliferative fibrocystic changes characterized by apocrine metaplasia, cyst formation, and multiple (2) fibroadenomas (upper inner quadrant, 0.9, and inferior central, 1.1 cm). A single left axillary lymph node is negative for tumor.

Estrogen and progesterone receptor analysis and Her-2/NEU have been ordered on paraffin embedded tissue from the right breast.

Dual/Synchronous Primary Mx Ted		X

Source: NCI Genomic Data Commons file 70e80c32-b101-4216-8787-54c2c441577d (TCGA-AR-A0TY.12A4A731-1ADF-4D36-88F3-16C9642484F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).